Somatic mutation profile of tumor specimen C3N-08899-01 (aliquot CPT0495370009) from CPTAC case C3N-08899, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 70.1 years (25,587 days).
Specimen C3N-08899-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d7c9804-1def-4d2a-8333-86bbad2cc51f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-08899-31 (Blood Derived Normal), aliquot CPT0495460006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3280a76f-9e7b-4f0d-8a39-35f1f6e250cb

The open-access MAF lists 1,132 somatic variants for this specimen: 710 protein-altering or splice-affecting, 371 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 644, Silent 371, Nonsense Mutation 36, Intron 29, Splice Region 12, Frame Shift Del 9, RNA 8, 5'Flank 6, 3'UTR 6, Splice Site 5, In Frame Del 2, Translation Start Site 2.

Variants (750 of 1,132; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 223/636 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913386, CM983988, COSV58683051, COSV58690307, COSV58692178; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- F8 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 147/245 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852364, CM055225, CM890046, COSV64270460; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 287/433 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.4092C>T p.A1364= (on ENST00000614293; = p.A1334= on NM_001606.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 50/172 reads (29%) | catalogued as rs771997297; called by muse, mutect2, varscan2
- ABCC4 | c.32A>G p.N11S | Missense Mutation (SNP) | VAF 116/376 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.191); catalogued as rs1275748455; called by muse, mutect2
- ABCG1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 102/307 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs564812607; called by muse, mutect2, varscan2
- AC126283.2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs748098641; called by muse, mutect2, varscan2
- ACSS3 | c.1344G>A p.W448* | Nonsense Mutation (SNP) | VAF 81/276 reads (29%) | catalogued as COSV54092441; called by muse, mutect2, varscan2
- ACSS3 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1247209581, COSV54084933; called by muse, mutect2, varscan2
- ADAM12 | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 132/362 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV64138586; called by muse, mutect2, varscan2
- ADAM28 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 97/300 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); catalogued as COSV56098649; called by muse, mutect2, varscan2
- ADD2 | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 99/384 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.635); catalogued as COSV52454333; called by muse, mutect2, varscan2
- ADGRL3 | c.4604G>A p.R1535K (on ENST00000506720 / NM_001322402.2; = p.R1424K on NM_015236.6) | Missense Mutation (SNP) | VAF 127/386 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.101); catalogued as COSV101541038; called by muse, mutect2, varscan2
- ADGRV1 | c.8005G>A p.E2669K | Missense Mutation (SNP) | VAF 112/348 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs757776405, COSV67983237; called by muse, mutect2, varscan2
- ADORA2A | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 196/574 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58379607; called by muse, mutect2, varscan2
- AGT | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 294/762 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs147355405, COSV64185672; called by muse, mutect2, varscan2
- ALK | c.1416G>A p.R472= | Splice Region (SNP) | VAF 84/256 reads (33%) | catalogued as rs1325368309, COSV66557174; called by muse, mutect2, varscan2
- ALLC | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 91/320 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV52994252; called by muse, mutect2, varscan2
- ALPK2 | c.4364C>T p.P1455L | Missense Mutation (SNP) | VAF 132/460 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as rs1460971016; called by muse, mutect2, varscan2
- ANGPT1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 95/342 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.15); catalogued as rs149379021, COSV52460175; called by muse, mutect2, varscan2
- ANKRD24 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 139/416 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs374166540, COSV104369309; called by muse, mutect2, varscan2
- ARIH2 | c.929G>A p.C310Y | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751798787, COSV100711397, COSV62706338; called by muse, mutect2, varscan2
- ASXL3 | c.5043G>A p.M1681I | Missense Mutation (SNP) | VAF 127/420 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as rs1333935790, COSV52466476; called by muse, mutect2, varscan2
- ATF5 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1172867290; called by mutect2, varscan2
- ATF7IP2 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 99/306 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); catalogued as rs369210238; called by muse, mutect2, varscan2
- BEND4 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 86/294 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs751350514, COSV72469111; called by muse, mutect2, varscan2
- BLK | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 126/455 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs755705290; called by muse, mutect2, varscan2
- BMPER | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 121/372 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.454); catalogued as COSV51815123; called by muse, mutect2, varscan2
- BNIP5 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 151/649 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs193920980, COSV71325445; ClinVar: uncertain significance; called by muse, varscan2
- BNIP5 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 160/716 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.457); catalogued as rs368937562; called by muse, varscan2
- BOLA1 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 194/986 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as rs782118083; called by muse, mutect2
- C10orf71 | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 161/477 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs757331659; called by muse, mutect2, varscan2
- C1QTNF7 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 133/390 reads (34%) | catalogued as COSV54851137; called by muse, mutect2, varscan2
- C6orf58 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 115/434 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as rs752615153, COSV61666486; called by muse, mutect2, varscan2
- CACNA1B | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 108/266 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200880829, COSV53142346; called by muse, mutect2, varscan2
- CACNA2D3 | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 118/353 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs772601031, COSV55554973; called by muse, mutect2, varscan2
- CACNA2D4 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 135/449 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773531067, COSV54953485; called by muse, mutect2, varscan2
- CALCRL | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 115/370 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV66475296; called by muse, mutect2, varscan2
- CAMK1D | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs267602410; called by muse, mutect2, varscan2
- CATSPERG | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 131/401 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1280096272; called by muse, mutect2, varscan2
- CBFA2T2 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 137/457 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.388); catalogued as rs1171744633, COSV100656105; called by muse, mutect2, varscan2
- CC2D2B | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 117/338 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1038283293; called by muse, mutect2, varscan2
- CCDC168 | c.14150G>A p.R4717Q | Missense Mutation (SNP) | VAF 130/412 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.294); catalogued as rs1024842352, COSV100487598; called by muse, mutect2, varscan2
- CCDC185 | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 274/675 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as rs757503039, COSV100838755; called by muse, mutect2, varscan2
- CCDC88C | c.2404G>A p.D802N | Missense Mutation (SNP) | VAF 137/445 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66234549; called by muse, mutect2, varscan2
- CCL25 | c.192-1G>A p.X64_splice | Splice Site (SNP) | VAF 117/290 reads (40%) | catalogued as COSV53664623; called by muse, mutect2, varscan2
- CCNF | c.1221C>T p.V407= | Splice Region (SNP) | VAF 59/217 reads (27%) | catalogued as rs1375557128; called by muse, mutect2, varscan2
- CCT2 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 99/285 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1055658846, COSV54739146; called by muse, mutect2, varscan2
- CDH16 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 124/452 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV55336288; called by muse, mutect2, varscan2
- CFAP206 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 84/307 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.666); catalogued as COSV51533516; called by muse, mutect2, varscan2
- CFAP46 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 119/383 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs539075445, COSV63950179; called by muse, mutect2, varscan2
- CFHR1 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 116/327 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs750501937, COSV100259003; called by muse, mutect2, varscan2
- CFHR5 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 71/471 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs868484373, COSV56819570; called by muse, mutect2, varscan2
- CHAT | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 134/423 reads (32%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as rs751461280, COSV60326568; called by muse, mutect2, varscan2
- CHD2 | c.63-1G>A p.X21_splice | Splice Site (SNP) | VAF 57/198 reads (29%) | catalogued as COSV59121900; called by muse, mutect2, varscan2
- CLVS1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 140/407 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.062); catalogued as rs1254755181, COSV57975251; called by muse, varscan2
- CMYA5 | c.6889G>A p.D2297N | Missense Mutation (SNP) | VAF 106/327 reads (32%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs377265303; called by muse, mutect2, varscan2
- CNTNAP2 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 77/259 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.268); catalogued as rs370057104; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP2 | c.1625G>A p.G542E | Missense Mutation (SNP) | VAF 85/304 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs372532510; called by muse, mutect2, varscan2
- CNTNAP4 | c.3907C>T p.Q1303* | Nonsense Mutation (SNP) | VAF 85/181 reads (47%) | catalogued as COSV56672293; called by muse, mutect2, varscan2
- COL3A1 | c.2480G>A p.R827K | Missense Mutation (SNP) | VAF 108/348 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1024288314; called by muse, mutect2, varscan2
- COL4A3 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780287240, COSV67421050; called by muse, mutect2, varscan2
- COL5A1 | c.2594G>A p.G865E | Missense Mutation (SNP) | VAF 113/337 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65671649; called by muse, mutect2, varscan2
- COQ7 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 92/300 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs746195092, COSV58981392; called by muse, mutect2, varscan2
- CORIN | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs200022892, COSV56693347; called by muse, mutect2, varscan2
- CPA4 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 116/385 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs767679396, COSV55984926; called by muse, mutect2, varscan2
- CPA6 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 65/263 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52729567; called by muse, mutect2, varscan2
- CPA6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 89/281 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as rs780746823; called by muse, mutect2, varscan2
- CPM | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 142/455 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs764807912; called by muse, mutect2, varscan2
- CPSF2 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 140/402 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54097860; called by muse, mutect2, varscan2
- CR2 | c.2309G>A p.G770E | Missense Mutation (SNP) | VAF 183/801 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV65506469; called by muse, mutect2, varscan2
- CR2 | c.3055G>A p.E1019K | Missense Mutation (SNP) | VAF 76/495 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as rs142489316; called by muse, mutect2, varscan2
- CRYBA1 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 262/512 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.851); catalogued as COSV56601713; called by muse, mutect2, varscan2
- CSMD1 | c.1591C>T p.P531S (on ENST00000520002; = p.P530S on NM_033225.6) | Missense Mutation (SNP) | VAF 104/336 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59326943; called by muse, mutect2, varscan2
- CTDP1 | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 153/566 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50009922; called by muse, mutect2, varscan2
- CYP4Z1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 165/263 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1206792114, COSV61964908; called by muse, mutect2, varscan2
- DAB2IP | c.2290C>T p.P764S (on ENST00000408936; = p.P736S on NM_032552.3) | Missense Mutation (SNP) | VAF 165/542 reads (30%) | SIFT tolerated (0.96); PolyPhen benign (0.031); catalogued as rs1564224558, COSV52255309; called by muse, mutect2, varscan2
- DARS2 | c.1780G>T p.G594* | Nonsense Mutation (SNP) | VAF 97/562 reads (17%) | catalogued as COSV99509001; called by muse, mutect2, varscan2
- DCC | c.4186C>T p.P1396S | Missense Mutation (SNP) | VAF 149/505 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV71431528; called by muse, mutect2, varscan2
- DCHS1 | c.4715C>G p.P1572R | Missense Mutation (SNP) | VAF 173/342 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as COSV55032117; called by muse, mutect2, varscan2
- DDX11 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 124/339 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV99299684; called by muse, mutect2, varscan2
- DGKQ | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 159/475 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs752810672; called by muse, mutect2, varscan2
- DKK2 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 123/347 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs770400633, COSV53394433; called by muse, mutect2, varscan2
- DNAAF3 | c.1133G>A p.G378D (on ENST00000524407 / NM_001256715.2; = p.G425D on NM_178837.4) | Missense Mutation (SNP) | VAF 82/340 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.445); catalogued as COSV61277872; called by muse, mutect2, varscan2
- DNAH17 | c.6112G>A p.D2038N | Missense Mutation (SNP) | VAF 200/403 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1226337189; called by muse, mutect2, varscan2
- DNAH5 | c.9609G>A p.M3203I | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.17); catalogued as COSV54234269; called by muse, mutect2, varscan2
- DPEP3 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 145/509 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52051376; called by muse, mutect2, varscan2
- DPPA4 | c.879G>A p.R293= | Splice Region (SNP) | VAF 60/208 reads (29%) | catalogued as COSV59511885, COSV59512452; called by muse, mutect2, varscan2
- DPPA4 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 173/515 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs990657669; called by muse, mutect2, varscan2
- DRGX | c.263G>A p.W88* | Nonsense Mutation (SNP) | VAF 118/369 reads (32%) | catalogued as COSV65137817; called by muse, mutect2, varscan2
- DSC3 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 80/352 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs868440269, COSV64571528, COSV64572714; called by muse, mutect2, varscan2
- DSG4 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 104/310 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768691954, COSV57388964; called by muse, mutect2, varscan2
- DSPP | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 84/276 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as CM1111035; called by muse, mutect2, varscan2
- DYNC1I2 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 75/271 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.047); catalogued as rs746866532; called by muse, mutect2, varscan2
- EDA2R | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 186/293 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs867588990, COSV53630915; called by muse, mutect2, varscan2
- EFCAB8 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 115/379 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1417711885; called by muse, mutect2, varscan2
- EFR3A | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 103/306 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1174181910, COSV54454132; called by muse, mutect2, varscan2
- ELOA2 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 153/460 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs765481551, COSV55300627; called by muse, mutect2, varscan2
- EML6 | c.2380G>A p.D794N | Missense Mutation (SNP) | VAF 112/321 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.707); catalogued as rs1343476384; called by muse, mutect2, varscan2
- ENPEP | c.2388T>G p.N796K | Missense Mutation (SNP) | VAF 104/388 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV99487714; called by muse, mutect2, varscan2
- ENTPD1 | c.1158G>A p.M386I | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV64600857; called by muse, mutect2, varscan2
- EPHA3 | c.2945C>T p.P982L | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV60698556, COSV60724231; called by muse, mutect2, varscan2
- ERAP2 | c.1762A>T p.I588F | Missense Mutation (SNP) | VAF 107/298 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs139804478; called by muse, mutect2, varscan2
- ERICH6B | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 126/347 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1472885249; called by muse, mutect2, varscan2
- ERVFRD-1 | c.1312T>C p.C438R | Missense Mutation (SNP) | VAF 148/634 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1561752341; called by muse, mutect2, varscan2
- ESPNL | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 126/378 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs756339637; called by muse, varscan2
- EVPL | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 162/717 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767324618, COSV56908538; called by muse, mutect2, varscan2
- EXD3 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 100/383 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.34); catalogued as rs750745784; called by muse, mutect2, varscan2
- FAM124B | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 149/470 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99706410, COSV99706500; called by muse, mutect2, varscan2
- FAM47C | c.1187A>G p.K396R | Missense Mutation (SNP) | VAF 160/257 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV100792587; called by muse, mutect2, varscan2
- FAP | c.1615C>A p.Q539K | Missense Mutation (SNP) | VAF 71/257 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV51865631; called by muse, mutect2, varscan2
- FAT3 | c.13108G>A p.E4370K | Missense Mutation (SNP) | VAF 91/215 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV53077133; called by muse, mutect2, varscan2
- FAT4 | c.6586G>A p.G2196S | Missense Mutation (SNP) | VAF 123/383 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779072662; called by muse, mutect2, varscan2
- FBXO39 | c.1203G>A p.A401= | Splice Region (SNP) | VAF 50/115 reads (43%) | catalogued as rs1240507393; called by muse, varscan2
- FCGRT | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 89/305 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1172109872; called by muse, mutect2, varscan2
- FCRL5 | c.1843G>A p.G615R | Missense Mutation (SNP) | VAF 257/654 reads (39%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as rs760631956, COSV62516564; called by muse, mutect2, varscan2
- FLRT2 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 104/374 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.559); catalogued as rs780318340; called by muse, mutect2, varscan2
- FRMPD2 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 102/276 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV59719860; called by muse, mutect2, varscan2
- GABRG1 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 83/238 reads (35%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.593); catalogued as rs1408329621, COSV54960467; called by muse, mutect2, varscan2
- GABRR3 | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 111/422 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1163158666; called by muse, mutect2, varscan2
- GALNT10 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 80/298 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561653928; called by muse, mutect2, varscan2
- GAPT | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 132/455 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868344368, COSV59246662; called by muse, mutect2, varscan2
- GDNF | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 129/359 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV58478338; called by muse, mutect2, varscan2
- GEMIN4 | c.2081C>A p.P694Q | Missense Mutation (SNP) | VAF 144/295 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100021362; called by muse, mutect2, varscan2
- GFRAL | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 103/343 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs527946821, COSV61229141, COSV61236470; called by muse, mutect2, varscan2
- GLDC | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 113/330 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV58677240; called by muse, mutect2, varscan2
- GLIS3 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 171/570 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1227142847, COSV100174622; called by muse, mutect2, varscan2
- GP2 | c.1133C>T p.S378F (on ENST00000381362 / NM_001007240.3; = p.S375F on NM_001502.4) | Missense Mutation (SNP) | VAF 111/392 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1185826790; called by muse, mutect2, varscan2
- GPAT2 | c.1715G>A p.G572E | Missense Mutation (SNP) | VAF 74/298 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764276045; called by muse, mutect2, varscan2
- GRIN3A | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 150/448 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV100701366, COSV62451578; called by muse, mutect2
- HELZ | c.1871C>T p.P624L | Missense Mutation (SNP) | VAF 80/388 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.306); catalogued as rs748364525; called by muse, mutect2, varscan2
- HNRNPCL1 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 488/1482 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV58609764; called by muse, mutect2, varscan2
- HNRNPCL1 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 205/890 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV100509030; called by muse, varscan2
- HRG | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 136/409 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.905); catalogued as rs776235094, COSV51645187; called by muse, mutect2, varscan2
- IGHV1-46 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 94/349 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1555524836; called by muse, varscan2
- IGHV2-70 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 96/374 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs556768737; called by muse, mutect2
- IGLV3-1 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 71/285 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.662); catalogued as rs370067205; called by muse, mutect2, varscan2
- IGSF21 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 167/263 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52141812; called by muse, mutect2, varscan2
- IKZF4 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 137/400 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs775603661; called by muse, mutect2, varscan2
- INSRR | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 292/750 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs759296297, COSV63873414; called by muse, mutect2, varscan2
- IQCA1L | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 89/335 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs1398058051; called by muse, varscan2
- ITGA1 | c.2719T>C p.F907L | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs1361429558; called by muse, mutect2, varscan2
- ITGA4 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as rs200211139, COSV52004271; called by muse, mutect2, varscan2
- JCHAIN | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs748096958; called by muse, mutect2, varscan2
- KCNH8 | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV60462237; called by muse, mutect2, varscan2
- KCNQ5 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 142/413 reads (34%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.203); catalogued as rs184951305, COSV100573017; called by muse, mutect2, varscan2
- KCNV1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 153/484 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0.037); catalogued as COSV52086156; called by muse, mutect2, varscan2
- KCTD16 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 83/259 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV72577197; called by muse, mutect2, varscan2
- KDM5B | c.3899A>G p.D1300G | Missense Mutation (SNP) | VAF 63/396 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1161253426; called by muse, mutect2
- KIAA1217 | c.5329C>T p.R1777C | Missense Mutation (SNP) | VAF 120/396 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs981789787, COSV56817798; called by muse, mutect2, varscan2
- KIAA1755 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 150/434 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs200662079, COSV54073418; called by muse, mutect2, varscan2
- KIAA2012 | c.2875G>A p.E959K | Missense Mutation (SNP) | VAF 139/423 reads (33%) | SIFT deleterious (0.04); catalogued as rs986948173; called by muse, mutect2, varscan2
- KIF12 | c.1028C>T p.S343F (on ENST00000640217; = p.S205F on NM_138424.1) | Missense Mutation (SNP) | VAF 91/288 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV65117167; called by muse, mutect2, varscan2
- KIR2DL3 | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV100667805; called by muse, mutect2, varscan2
- KMT2B | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 262/786 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.28); catalogued as rs767027293; called by muse, mutect2, varscan2
- KRTAP10-11 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 172/597 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.385); catalogued as rs1385139128; called by muse, mutect2, varscan2
- KRTAP10-8 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 134/448 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs1041490732; called by muse, mutect2, varscan2
- LALBA | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 153/431 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.479); catalogued as COSV56395462; called by muse, mutect2, varscan2
- LCE2C | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 326/930 reads (35%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.217); catalogued as COSV64228305; called by muse, mutect2, varscan2
- LGALS9 | c.782G>A p.G261E (on ENST00000395473 / NM_009587.3; = p.G229E on NM_002308.4) | Missense Mutation (SNP) | VAF 239/528 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100119461; called by muse, mutect2, varscan2
- LHX8 | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 269/412 reads (65%) | SIFT tolerated (0.74); PolyPhen benign (0.125); catalogued as COSV53954502, COSV53960616; called by muse, mutect2, varscan2
- LIPI | c.1021C>T p.L341F | Missense Mutation (SNP) | VAF 92/300 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as COSV60714818; called by muse, mutect2, varscan2
- LRP1B | c.3142C>T p.H1048Y | Missense Mutation (SNP) | VAF 73/229 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs751861711; called by muse, mutect2, varscan2
- MAB21L4 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 104/364 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.025); catalogued as rs1003651122, COSV100278522; called by muse, mutect2, varscan2
- MAP1A | c.5728C>T p.R1910C | Missense Mutation (SNP) | VAF 144/449 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs764432579, COSV55810238; called by muse, mutect2, varscan2
- MARK1 | c.1249C>T p.Q417* | Nonsense Mutation (SNP) | VAF 89/473 reads (19%) | catalogued as COSV100857571; called by muse, mutect2, varscan2
- MBP | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 131/446 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV62829651; called by muse, mutect2, varscan2
- MEP1B | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 127/380 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320548902, COSV52499975; called by muse, mutect2, varscan2
- MGAM2 | c.2238G>A p.W746* | Nonsense Mutation (SNP) | VAF 95/253 reads (38%) | catalogued as rs1433170430; called by muse, mutect2, varscan2
- MGAT4C | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 91/315 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as COSV59833687; called by muse, mutect2, varscan2
- MOV10L1 | c.3320C>T p.S1107L | Missense Mutation (SNP) | VAF 80/256 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53167559; called by muse, mutect2, varscan2
- MRTFB | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 83/426 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1409853586, COSV100371971; called by muse, mutect2, varscan2
- MSR1 | c.401A>G p.N134S | Missense Mutation (SNP) | VAF 175/510 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as COSV50506633; called by muse, mutect2, varscan2
- MTMR3 | c.2678C>T p.P893L | Missense Mutation (SNP) | VAF 147/481 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV60304257; called by muse, mutect2, varscan2
- MUC12 | c.8723C>T p.S2908L (on ENST00000379442; = p.S2765L on NM_001164462.1) | Missense Mutation (SNP) | VAF 242/3558 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.702); catalogued as rs764483499; called by muse, mutect2
- MUC16 | c.20876C>T p.S6959F | Missense Mutation (SNP) | VAF 134/396 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.414); catalogued as COSV67454402; called by muse, mutect2, varscan2
- MUC16 | c.17071A>G p.S5691G | Missense Mutation (SNP) | VAF 187/520 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as rs747790183, COSV67445403; called by muse, mutect2, varscan2
- MYCBPAP | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 101/420 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.278); catalogued as COSV60412293; called by muse, mutect2, varscan2
- MYH13 | c.4380G>A p.W1460* | Nonsense Mutation (SNP) | VAF 78/195 reads (40%) | catalogued as COSV52831443; called by muse, mutect2, varscan2
- MYH4 | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 163/317 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs200153692, COSV55112344; called by muse, mutect2, varscan2
- MYO7B | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 185/507 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV67351421; called by muse, mutect2, varscan2
- NAV3 | c.6538C>T p.H2180Y (on ENST00000397909 / NM_001024383.2; = p.H2158Y on NM_014903.6) | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57110552; called by muse, mutect2, varscan2
- NCAM1 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 116/274 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV57514443; called by muse, mutect2, varscan2
- NCAM2 | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 115/429 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs757374731, COSV53082619; called by muse, mutect2, varscan2
- NDUFAF7 | c.844_846del p.I282del | In Frame Del (DEL) | VAF 107/442 reads (24%) | catalogued as rs747186021; called by pindel, varscan2
- NEFM | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 159/496 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs368440835; called by muse, mutect2, varscan2
- NKG7 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 105/311 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99389788; called by muse, mutect2, varscan2
- NLRC5 | c.3943C>T p.R1315W | Missense Mutation (SNP) | VAF 101/242 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs768031202; called by muse, mutect2, varscan2
- NLRP12 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.037); catalogued as rs753733591, COSV60753598; called by muse, mutect2, varscan2
- NLRP3 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 275/700 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV60219497; called by muse, mutect2, varscan2
- NPAP1 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 130/404 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.801); catalogued as rs868115699, COSV61504054; called by muse, mutect2, varscan2
- NPAP1 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 118/346 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as rs1473780880; called by muse, mutect2, varscan2
- NPY5R | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 102/313 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs866941603, COSV58451682; called by muse, mutect2, varscan2
- NRAP | c.3905T>A p.I1302K (on ENST00000359988 / NM_001322945.2; = p.I1267K on NM_006175.4) | Missense Mutation (SNP) | VAF 97/295 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV100748464; called by muse, mutect2, varscan2
- NTN4 | c.1860G>A p.M620I | Missense Mutation (SNP) | VAF 87/283 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.113); catalogued as rs1303161283; called by muse, mutect2, varscan2
- NTN4 | c.1579G>A p.V527M | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100643752; called by muse, mutect2, varscan2
- NTN5 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 160/494 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs568145062; called by muse, varscan2
- NUAK1 | c.1355G>A p.G452E | Missense Mutation (SNP) | VAF 144/427 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs1157642732, COSV54608178; called by muse, mutect2, varscan2
- OAZ1 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 120/414 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as COSV59233392; called by muse, mutect2, varscan2
- OR1L8 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as rs771093917, COSV59185779; called by muse, mutect2, varscan2
- OR2A2 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 107/379 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs779883967; called by muse, mutect2, varscan2
- OR2AG1 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 114/242 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as rs992391530; called by muse, mutect2, varscan2
- OR2T1 | c.-33-1G>A | Splice Site (SNP) | VAF 302/849 reads (36%) | catalogued as COSV63542858; called by muse, mutect2, varscan2
- OR4A8 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); catalogued as rs113110045; called by muse, mutect2
- OR4P4 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 133/270 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs1192342728, COSV58921470; called by muse, mutect2, varscan2
- OR51B2 | c.508C>T p.H170Y | Missense Mutation (SNP) | VAF 97/225 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs1262721090, COSV60916027; called by muse, mutect2, varscan2
- OR51G2 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 107/248 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58992960; called by muse, mutect2, varscan2
- OR52B4 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 118/258 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as rs778991316, COSV68768572; called by muse, mutect2, varscan2
- OR5K1 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 139/461 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60304918; called by muse, mutect2, varscan2
- OR6K6 | c.238G>T p.G80C (on ENST00000368144; = p.G56C on NM_001005184.1) | Missense Mutation (SNP) | VAF 208/530 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1265998303, COSV63745159; called by muse, mutect2, varscan2
- OSBPL6 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 145/441 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs748675044, COSV51911276; called by muse, mutect2, varscan2
- OTOF | c.2407G>A p.E803K (on ENST00000272371 / NM_194248.3; = p.E56K on NM_004802.4) | Missense Mutation (SNP) | VAF 97/261 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs758618543; called by muse, mutect2, varscan2
- OTOL1 | c.1111G>A p.G371R | Missense Mutation (SNP) | VAF 136/393 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs1229312019; called by muse, mutect2, varscan2
- PAPPA2 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 165/801 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV62778733; called by muse, mutect2, varscan2
- PARP3 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 130/440 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV51754591; called by muse, mutect2, varscan2
- PARP4 | c.3737C>T p.S1246F | Missense Mutation (SNP) | VAF 91/378 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as rs558059709, COSV67962642; called by muse, mutect2
- PCDH18 | c.3340G>A p.E1114K | Missense Mutation (SNP) | VAF 106/389 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61267754; called by muse, mutect2, varscan2
- PCDHA3 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 91/301 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as rs557580137; called by muse, mutect2, varscan2
- PCDHAC2 | c.1559C>T p.S520F | Missense Mutation (SNP) | VAF 107/330 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs148804197; called by muse, mutect2, varscan2
- PCDHB12 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 150/446 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV53394680; called by muse, mutect2, varscan2
- PCDHB9 | c.2000C>T p.S667F | Missense Mutation (SNP) | VAF 192/1446 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1554283313; called by muse, mutect2, varscan2
- PCDHGA1 | c.1183G>T p.E395* | Nonsense Mutation (SNP) | VAF 94/308 reads (31%) | catalogued as COSV65295945; called by muse, mutect2, varscan2
- PCDHGA1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 130/371 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.055); catalogued as COSV65295349; called by muse, mutect2, varscan2
- PCDHGA5 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 136/465 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53974388; called by muse, mutect2, varscan2
- PDE4B | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 132/212 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58466341; called by muse, mutect2, varscan2
- PDK4 | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 119/342 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV50011140; called by muse, mutect2, varscan2
- PDZD2 | c.3454C>T p.P1152S | Missense Mutation (SNP) | VAF 116/382 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1345684620; called by muse, mutect2, varscan2
- PEG3 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 148/447 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV55624758, COSV55640636; called by muse, mutect2, varscan2
- PIEZO2 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 115/392 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.028); catalogued as COSV57448680; called by muse, mutect2, varscan2
- PKHD1L1 | c.6563G>A p.G2188E | Missense Mutation (SNP) | VAF 82/323 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369320445, COSV65742451; called by muse, varscan2
- PKHD1L1 | c.6625G>A p.D2209N | Missense Mutation (SNP) | VAF 74/261 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs950914784; called by muse, varscan2
- PKHD1L1 | c.12295C>T p.P4099S | Missense Mutation (SNP) | VAF 98/333 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1301099886; called by muse, mutect2, varscan2
- PLA2G4A | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 231/628 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748817539, COSV66557777; called by muse, mutect2, varscan2
- PLCH1 | c.118C>T p.R40C (on ENST00000340059 / NM_001130960.2; = p.R52C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 164/447 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769082766, COSV58211285; called by muse, mutect2, varscan2
- PLEKHS1 | c.443G>A p.R148K (on ENST00000369310 / NM_182601.1; = p.R154K on NM_024889.5) | Missense Mutation (SNP) | VAF 82/274 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.826); catalogued as COSV63054736; called by muse, mutect2, varscan2
- PLVAP | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 134/424 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370989890, COSV53086432; called by muse, mutect2, varscan2
- POLA1 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 107/181 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV66890639; called by muse, mutect2, varscan2
- POM121L12 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 206/660 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.798); catalogued as rs746175412, COSV68692799; called by muse, mutect2
- POTEF | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 36/482 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as rs546573251; called by muse, mutect2
- POTEM | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as COSV66935981; called by mutect2, varscan2
- PRDM16 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 312/484 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs753255714, COSV54591693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRG3 | c.482G>A p.W161* | Nonsense Mutation (SNP) | VAF 114/217 reads (53%) | catalogued as COSV54663612; called by muse, mutect2, varscan2
- PRKCB | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 130/386 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV57764394, COSV57798836; called by muse, mutect2, varscan2
- PRR32 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 197/305 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs887535258, COSV64420781; called by muse, mutect2, varscan2
- PRRC2C | c.6674C>T p.P2225L (on ENST00000367742; = p.P2223L on NM_015172.4) | Missense Mutation (SNP) | VAF 99/536 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs770185948; called by muse, mutect2, varscan2
- PRSS35 | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 116/398 reads (29%) | catalogued as COSV63801000; called by muse, mutect2, varscan2
- PRUNE2 | c.7306G>A p.D2436N | Missense Mutation (SNP) | VAF 138/467 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.681); catalogued as COSV65041629; called by muse, mutect2, varscan2
- PSD2 | c.1377C>G p.I459M | Missense Mutation (SNP) | VAF 122/383 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51197677; called by muse, mutect2, varscan2
- PSD2 | c.2042C>T p.P681L | Missense Mutation (SNP) | VAF 195/461 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs1375393042; called by muse, mutect2, varscan2
- PSG3 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 118/505 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.893); catalogued as COSV100549174; called by muse, mutect2, varscan2
- PTPRD | c.4999C>T p.P1667S | Missense Mutation (SNP) | VAF 111/376 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs778721966; called by muse, mutect2, varscan2
- PTPRE | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 136/425 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs369714622; called by muse, mutect2, varscan2
- PTPRF | c.2688C>G p.N896K | Missense Mutation (SNP) | VAF 302/440 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1186558185, COSV63446352; called by muse, mutect2, varscan2
- PTPRS | c.4549C>T p.Q1517* | Nonsense Mutation (SNP) | VAF 118/370 reads (32%) | catalogued as rs1236009082, COSV53611177; called by muse, mutect2, varscan2
- PYROXD1 | c.1268G>A p.G423E | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1485788448; called by muse, mutect2, varscan2
- RAB27B | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV50494213; called by muse, mutect2, varscan2
- RABGAP1L | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 161/423 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52296814; called by muse, mutect2, varscan2
- RAD18 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 138/416 reads (33%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV53753359, COSV99368098; called by muse, mutect2, varscan2
- RBFOX1 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 91/318 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs1002449097, COSV60950777, COSV60972926; called by muse, mutect2, varscan2
- RELN | c.10246G>A p.D3416N | Missense Mutation (SNP) | VAF 109/364 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV58998133; called by muse, mutect2, varscan2
- RELN | c.4589G>T p.G1530V | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756855458; called by muse, mutect2, varscan2
- RGPD4 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 97/153 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs746649494; called by muse, mutect2, varscan2
- RHPN1 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 170/518 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs780984814; called by muse, mutect2, varscan2
- RHPN2 | c.69G>A p.K23= | Splice Region (SNP) | VAF 91/263 reads (35%) | catalogued as rs1014039877; called by muse, mutect2, varscan2
- RIPPLY3 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 108/367 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs143693644; called by muse, mutect2, varscan2
- RNASE9 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 136/453 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.198); catalogued as COSV58880185; called by muse, mutect2, varscan2
- RNF17 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 111/388 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs762842516; called by muse, mutect2, varscan2
- RP1 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 161/490 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs149197814; called by muse, mutect2, varscan2
- RUSC2 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 119/382 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs534812809, COSV63429019; called by muse, mutect2, varscan2
- RYR2 | c.7084C>T p.P2362S | Missense Mutation (SNP) | VAF 84/485 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); catalogued as COSV63720759; called by muse, mutect2, varscan2
- SALL3 | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 189/595 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.118); catalogued as COSV73305823; called by muse, mutect2, varscan2
- SAMD3 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 123/380 reads (32%) | catalogued as rs1024980652, COSV60773958; called by muse, mutect2, varscan2
- SCAF8 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 75/281 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1316931343; called by muse, mutect2, varscan2
- SDK1 | c.3400G>A p.E1134K | Missense Mutation (SNP) | VAF 97/283 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs373096265; called by muse, mutect2, varscan2
- SEC31B | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 128/389 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.853); catalogued as rs779967089; called by muse, mutect2, varscan2
- SEMA4F | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 179/536 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751185275, COSV60282439; called by muse, mutect2, varscan2
- SEMA6B | c.2657C>T p.P886L | Missense Mutation (SNP) | VAF 124/362 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as rs1049242845; called by muse, mutect2, varscan2
- SERPINA5 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 177/460 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs866630753, COSV61573556, COSV61574034; called by muse, mutect2, varscan2
- SETD1A | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 145/463 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769466073, COSV99353911; called by muse, mutect2, varscan2
- SH2D4B | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 74/199 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.331); catalogued as rs977749080, COSV57892858; called by muse, mutect2, varscan2
- SH3GL3 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 108/350 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs374787134; called by muse, mutect2, varscan2
- SH3GLB1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 170/318 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1164018187; called by muse, mutect2, varscan2
- SIRT4 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 130/409 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769184129, COSV52541534, COSV52542394; called by muse, mutect2, varscan2
- SLC10A1 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 137/466 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1416975343, COSV99384395; called by muse, mutect2, varscan2
- SLC12A1 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 114/338 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs752019810; called by muse, mutect2, varscan2
- SLC15A2 | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 115/320 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV55197368; called by muse, mutect2, varscan2
- SLC15A2 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 71/338 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55197996; called by muse, mutect2
- SLC17A7 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 85/276 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs767393135, COSV55548631; called by muse, mutect2, varscan2
- SLC18A1 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 82/274 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52346648; called by muse, mutect2, varscan2
- SLC22A10 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 108/255 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs1226727499, COSV60421521; called by muse, mutect2, varscan2
- SLC27A6 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs1315273250, COSV52482732; called by muse, mutect2, varscan2
- SLC2A12 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 132/338 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1047848491; called by muse, mutect2, varscan2
- SLC35C2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 123/430 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs772484930, COSV54757056; called by muse, mutect2, varscan2
- SLC44A4 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 165/423 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs371013029; called by muse, mutect2, varscan2
- SLC45A1 | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 422/634 reads (67%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as COSV57096129; called by muse, mutect2, varscan2
- SLC7A13 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 149/449 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs751158410, COSV52533339; called by muse, mutect2, varscan2
- SLC7A8 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 129/405 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766602132, COSV57553409; called by muse, mutect2, varscan2
- SLC9C2 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 74/494 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62944626; called by muse, mutect2, varscan2
- SLCO2A1 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 100/339 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs555934769, CM126915; called by muse, mutect2, varscan2
- SLIT3 | c.2042G>A p.R681K | Missense Mutation (SNP) | VAF 158/532 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as rs996605370; called by muse, mutect2
- SLX4IP | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 162/458 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs143257409; called by muse, mutect2, varscan2
- SOHLH2 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 98/345 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV101158006; called by muse, mutect2, varscan2
- SORCS2 | c.3046G>A p.D1016N | Missense Mutation (SNP) | VAF 114/417 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs759118679, COSV61171167; called by muse, mutect2, varscan2
- SPINK5 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 53/278 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375796789; called by muse, mutect2, varscan2
- SPINK7 | c.213G>A p.L71= | Splice Region (SNP) | VAF 79/286 reads (28%) | catalogued as COSV99199113; called by muse, mutect2, varscan2
- SPRR2E | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 328/1033 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.125); catalogued as COSV64203746; called by muse, varscan2
- SPTAN1 | c.5293C>T p.R1765C | Missense Mutation (SNP) | VAF 158/461 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs371055930; called by muse, mutect2, varscan2
- SRRT | c.1936C>T p.R646W | Missense Mutation (SNP) | VAF 123/394 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1432025934, COSV53821479; called by muse, mutect2, varscan2
- STAT4 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 100/319 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.739); catalogued as rs759785386, COSV61828730; called by muse, mutect2, varscan2
- STMN2 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 86/279 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV55218550; called by muse, mutect2, varscan2
- STON2 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 182/561 reads (32%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.024); catalogued as rs770491073; called by muse, mutect2, varscan2
- SVEP1 | c.4681G>A p.G1561R | Missense Mutation (SNP) | VAF 143/364 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1239199159, COSV104429157, COSV65680070; called by muse, mutect2, varscan2
- SYNE1 | c.5962G>A p.E1988K (on ENST00000367255 / NM_182961.4; = p.E1995K on NM_033071.3) | Missense Mutation (SNP) | VAF 151/454 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV54944314; called by muse, mutect2, varscan2
- SYT10 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 126/423 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.208); catalogued as rs370751808; called by muse, mutect2, varscan2
- TACC2 | c.4454C>T p.S1485F | Missense Mutation (SNP) | VAF 151/452 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.311); catalogued as rs771707264, COSV57772152; called by muse, mutect2, varscan2
- TBC1D1 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 148/509 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as rs150670938; called by muse, mutect2, varscan2
- TECPR1 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 116/383 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as rs1484864744; called by muse, mutect2, varscan2
- TENM2 | c.7987C>T p.R2663* (on ENST00000518659 / NM_001122679.2; = p.R2424* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 171/495 reads (35%) | catalogued as COSV69128070; called by muse, mutect2, varscan2
- TENM4 | c.7468C>T p.P2490S | Missense Mutation (SNP) | VAF 153/297 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV99575934; called by muse, mutect2, varscan2
- TET2 | c.5203G>A p.G1735R | Missense Mutation (SNP) | VAF 106/367 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV54398523, COSV54409297; called by muse, mutect2, varscan2
- TET3 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 129/461 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99996673; called by muse, mutect2, varscan2
- TGM5 | c.1975G>A p.G659R (on ENST00000220420 / NM_201631.4; = p.G577R on NM_004245.4) | Missense Mutation (SNP) | VAF 127/435 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1235265199; called by muse, mutect2, varscan2
- THBS1 | c.2776C>T p.R926* | Nonsense Mutation (SNP) | VAF 79/249 reads (32%) | catalogued as rs755652372, COSV52950300; called by muse, mutect2, varscan2
- THBS1 | c.3058G>A p.D1020N | Missense Mutation (SNP) | VAF 155/441 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767595971; called by muse, mutect2, varscan2
- THSD7B | c.2783C>T p.S928F | Missense Mutation (SNP) | VAF 118/404 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV55671119, COSV55730929; called by muse, mutect2, varscan2
- TLCD2 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 101/217 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as rs533525631, COSV58007820; called by muse, mutect2, varscan2
- TLR4 | c.424G>A p.E142K (on ENST00000355622 / NM_138554.5; = p.E102K on NM_003266.4) | Missense Mutation (SNP) | VAF 113/361 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV100790571; called by muse, mutect2, varscan2
- TMPRSS11B | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.137); catalogued as COSV60293648; called by muse, mutect2, varscan2
- TMPRSS9 | c.79C>G p.R27G | Missense Mutation (SNP) | VAF 173/514 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); catalogued as rs536159570; called by muse, mutect2, varscan2
- TNIK | c.3529C>T p.H1177Y | Missense Mutation (SNP) | VAF 96/294 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV52699166; called by muse, mutect2, varscan2
- TNRC6C | c.2778G>A p.K926= | Splice Region (SNP) | VAF 73/315 reads (23%) | catalogued as rs1388230044; called by muse, mutect2, varscan2
- TOR2A | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 126/464 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100137909; called by muse, mutect2, varscan2
- TPTE | c.796G>A p.E266K (on ENST00000618007 / NM_199261.4; = p.E248K on NM_199259.4) | Missense Mutation (SNP) | VAF 74/497 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs1328516038; called by muse, varscan2
- TPTE | c.838C>T p.R280* (on ENST00000618007 / NM_199261.4; = p.R262* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 69/520 reads (13%) | catalogued as rs755481692; called by muse, varscan2
- TRAF3IP1 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 68/287 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as rs780340828; called by muse, mutect2, varscan2
- TRANK1 | c.1967G>A p.G656E | Missense Mutation (SNP) | VAF 148/461 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV57151418; called by muse, mutect2, varscan2
- TRAPPC10 | c.884C>T p.S295L | Missense Mutation (SNP) | VAF 120/373 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754988460; called by muse, mutect2, varscan2
- TRAV9-1 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 119/370 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as rs933975491; called by muse, mutect2, varscan2
- TRIM2 | c.305C>T p.S102F (on ENST00000437508; = p.S129F on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 165/500 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV58636842; called by muse, mutect2, varscan2
- TRIM55 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 96/347 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as rs574439941, COSV52545753, COSV52549303; called by muse, mutect2, varscan2
- TTN | c.79216C>T p.P26406S (on ENST00000591111; = p.P18982S on NM_003319.4) | Missense Mutation (SNP) | VAF 118/386 reads (31%) | PolyPhen benign (0.001); catalogued as rs1390232115; called by muse, mutect2, varscan2
- TTN | c.77218G>A p.G25740R (on ENST00000591111; = p.G18316R on NM_003319.4) | Missense Mutation (SNP) | VAF 127/419 reads (30%) | PolyPhen possibly damaging (0.758); catalogued as COSV60280602; called by muse, mutect2, varscan2
- TTN | c.48901G>A p.E16301K (on ENST00000591111; = p.E8877K on NM_003319.4) | Missense Mutation (SNP) | VAF 80/249 reads (32%) | PolyPhen benign (0.033); catalogued as COSV60169071; called by muse, mutect2, varscan2
- TTN | c.43729G>A p.G14577S (on ENST00000591111; = p.G7153S on NM_003319.4) | Missense Mutation (SNP) | VAF 52/187 reads (28%) | PolyPhen possibly damaging (0.651); catalogued as rs566086846; called by muse, mutect2, varscan2
- TTN | c.12910G>A p.D4304N (on ENST00000591111; = p.D4258N on NM_003319.4) | Missense Mutation (SNP) | VAF 135/409 reads (33%) | catalogued as rs868416442, COSV60045188; called by muse, mutect2, varscan2
- TTN | c.4556C>T p.P1519L (on ENST00000591111; = p.P1473L on NM_003319.4) | Missense Mutation (SNP) | VAF 109/416 reads (26%) | PolyPhen probably damaging (0.999); catalogued as rs1422993371, COSV100614375; called by muse, mutect2, varscan2
- TTN | c.3853G>A p.E1285K (on ENST00000591111; = p.E1239K on NM_003319.4) | Missense Mutation (SNP) | VAF 96/262 reads (37%) | PolyPhen possibly damaging (0.894); catalogued as COSV100596885; called by muse, mutect2, varscan2
- TXNRD2 | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 87/285 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68692369; called by muse, mutect2, varscan2
- UBASH3A | c.1272G>A p.G424= | Splice Region (SNP) | VAF 72/272 reads (26%) | catalogued as rs773560755, COSV52310291; called by muse, mutect2
- UGT2B28 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 82/140 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV59430819, COSV59433399; called by muse, mutect2, varscan2
- UNC13C | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 71/268 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as rs758672263, COSV52886684; called by muse, mutect2, varscan2
- USH2A | c.7475C>T p.S2492L | Missense Mutation (SNP) | VAF 193/498 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs483353056, CM154359, COSV56432156; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP17L1 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 90/323 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as rs1265669757; called by muse, mutect2, varscan2
- USP18 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 144/449 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1468164582; called by muse, mutect2, varscan2
- VPS37B | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 116/421 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as COSV53444593; called by muse, mutect2, varscan2
- VPS54 | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 109/359 reads (30%) | catalogued as COSV55439554; called by muse, mutect2, varscan2
- WDR33 | c.3158C>T p.P1053L | Missense Mutation (SNP) | VAF 184/563 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs377069025; called by muse, mutect2, varscan2
- WDR49 | c.668G>A p.G223E (on ENST00000308378 / NM_001366158.1; = p.G564E on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/231 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV57706517, COSV57718553; called by muse, mutect2, varscan2
- WDR72 | c.2677G>A p.D893N | Missense Mutation (SNP) | VAF 102/322 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV64742268; called by muse, mutect2, varscan2
- WFDC10B | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 103/327 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100224950, COSV100225239; called by muse, mutect2, varscan2
- WFDC9 | c.102G>A p.M34I | Missense Mutation (SNP) | VAF 66/235 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs764599219, COSV58097411; called by muse, mutect2, varscan2
- WIZ | c.2720C>T p.P907L (on ENST00000673675 / NM_001371589.1; = p.P170L on NM_021241.3) | Missense Mutation (SNP) | VAF 133/369 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV54608082; called by muse, mutect2, varscan2
- XIRP2 | c.6790G>A p.D2264N (on ENST00000628543; = p.D2439N on NM_152381.6) | Missense Mutation (SNP) | VAF 125/439 reads (28%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs563915541, COSV54679859; called by muse, mutect2, varscan2
- XKR9 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 105/327 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV68772737; called by muse, mutect2, varscan2
- ZAN | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 131/484 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV100770519, COSV61805947; called by mutect2, varscan2
- ZC3HAV1 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 99/306 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV54300368; called by muse, mutect2, varscan2
- ZFPM2 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 136/412 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765404652, COSV65873778; called by muse, mutect2, varscan2
- ZNF155 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 113/338 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV54206532; called by muse, mutect2, varscan2
- ZNF227 | c.752C>A p.P251Q | Missense Mutation (SNP) | VAF 111/362 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.047); catalogued as COSV57313752; called by muse, mutect2, varscan2
- ZNF334 | c.728G>A p.R243K | Missense Mutation (SNP) | VAF 135/383 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs866288648, COSV100749177; called by muse, mutect2, varscan2
- ZNF560 | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 149/485 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as COSV100039021; called by muse, mutect2, varscan2
- ZNF700 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 128/422 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV54310844, COSV99583864; called by muse, mutect2, varscan2
- ZNF711 | c.2161C>T p.R721* | Nonsense Mutation (SNP) | VAF 176/252 reads (70%) | catalogued as COSV52159394; called by muse, mutect2, varscan2
- ZNF736 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 108/404 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1448642218; called by muse, mutect2
- ZNF800 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 97/344 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99757895; called by muse, mutect2, varscan2
- ZNF91 | c.1841C>T p.S614F | Missense Mutation (SNP) | VAF 111/343 reads (32%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.582); catalogued as rs755004095; called by muse, mutect2, varscan2
- ZNF99 | c.667C>T p.H223Y | Missense Mutation (SNP) | VAF 63/256 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV68056736; called by muse, mutect2, varscan2
- ZSWIM2 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 87/251 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV54580846; called by muse, mutect2, varscan2
- ABAT | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 83/291 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ABCC1 | c.2926T>C p.F976L | Missense Mutation (SNP) | VAF 160/534 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ABL1 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 101/387 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- AC004593.2 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 104/338 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACAN | c.6985G>A p.A2329T | Missense Mutation (SNP) | VAF 128/380 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ACVRL1 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 167/546 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ADGRB3 | c.2378G>A p.R793K | Missense Mutation (SNP) | VAF 109/334 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- AHNAK | c.104A>G p.Q35R | Missense Mutation (SNP) | VAF 161/340 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AMBN | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 99/363 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- AMOTL2 | c.529del p.H177Tfs*2 | Frame Shift Del (DEL) | VAF 155/573 reads (27%) | called by mutect2, pindel, varscan2
- ANK1 | c.5620G>A p.D1874N | Missense Mutation (SNP) | VAF 114/368 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- ANKRD30A | c.1727C>T p.S576L (on ENST00000611781; = p.S520L on NM_052997.2) | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, varscan2
- APBA2 | c.1176C>G p.I392M | Missense Mutation (SNP) | VAF 116/527 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); called by muse, varscan2
- APOBEC3A | c.68del p.N23Tfs*98 | Frame Shift Del (DEL) | VAF 135/494 reads (27%) | called by mutect2, pindel, varscan2
- APOL4 | c.316G>A p.E106K (on ENST00000352371 / NM_145660.2; = p.E103K on NM_030643.4) | Missense Mutation (SNP) | VAF 106/309 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- ARHGAP22 | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 177/554 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF17 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 155/317 reads (49%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARHGEF17 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 155/322 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ARID1A | c.3897del p.N1299Kfs*2 | Frame Shift Del (DEL) | VAF 223/513 reads (43%) | called by pindel, varscan2
- ARSI | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 93/306 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ATP2B4 | c.2710C>T p.P904S | Missense Mutation (SNP) | VAF 184/994 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ATP6V1B1 | c.227G>T p.R76M | Missense Mutation (SNP) | VAF 119/403 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BBX | c.2510G>A p.R837K (on ENST00000325805 / NM_001142568.3; = p.R807K on NM_020235.7) | Missense Mutation (SNP) | VAF 122/347 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BPIFB3 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 118/336 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- BRD9 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 126/398 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.041); called by muse, mutect2
- C10orf71 | c.3676G>A p.E1226K | Missense Mutation (SNP) | VAF 159/509 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- C12orf42 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 130/466 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- C20orf96 | c.757A>T p.K253* (on ENST00000360321 / NM_153269.3; = p.K252* on NM_080571.1) | Nonsense Mutation (SNP) | VAF 87/311 reads (28%) | called by muse, mutect2, varscan2
- C2orf42 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 141/382 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C4BPA | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 188/508 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.134); called by muse, varscan2
- C9orf131 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 145/502 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- C9orf131 | c.2609C>A p.S870Y | Missense Mutation (SNP) | VAF 125/423 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- CAMK2B | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 111/361 reads (31%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CAVIN2 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 191/548 reads (35%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- CC2D2B | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 79/277 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC168 | c.15652G>A p.G5218R | Missense Mutation (SNP) | VAF 109/402 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CCDC168 | c.11782G>A p.E3928K | Missense Mutation (SNP) | VAF 133/388 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- CCDC174 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 102/341 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC180 | c.4957C>T p.Q1653* | Nonsense Mutation (SNP) | VAF 103/253 reads (41%) | called by muse, mutect2
- CCNB3 | c.3080T>G p.F1027C | Missense Mutation (SNP) | VAF 182/282 reads (65%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- CCR1 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- CD163 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 136/366 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD163L1 | c.4250G>A p.R1417K | Missense Mutation (SNP) | VAF 82/282 reads (29%) | SIFT tolerated (0.91); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CDC42BPB | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 93/281 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH17 | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 88/292 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CDX1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 129/406 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CELSR3 | c.6457C>T p.P2153S | Missense Mutation (SNP) | VAF 101/356 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CENPJ | c.1742T>C p.L581S | Missense Mutation (SNP) | VAF 95/296 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CEP170B | c.1460C>T p.P487L (on ENST00000453495; = p.P416L on NM_015005.3) | Missense Mutation (SNP) | VAF 194/640 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CEP290 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 65/254 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- CGA | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 87/286 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- CHAMP1 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 142/473 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CHN1 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 83/347 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CHPF2 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 165/454 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHRNA1 | c.574G>A p.G192S (on ENST00000261007 / NM_001039523.3; = p.G167S on NM_000079.4) | Missense Mutation (SNP) | VAF 116/398 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLECL1 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 119/417 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- CMAS | c.899T>G p.I300R | Missense Mutation (SNP) | VAF 79/286 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- COL7A1 | c.4006G>A p.D1336N | Missense Mutation (SNP) | VAF 146/479 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CP | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 133/381 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRACDL | c.1921G>A p.G641R | Missense Mutation (SNP) | VAF 140/512 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CRISP3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 76/282 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, varscan2
- CS | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 127/416 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CSMD1 | c.7268G>A p.G2423E (on ENST00000520002; = p.G2422E on NM_033225.6) | Missense Mutation (SNP) | VAF 93/300 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTNNB1 | c.1005A>C p.K335N | Missense Mutation (SNP) | VAF 106/377 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CTNND2 | c.3655G>A p.A1219T | Missense Mutation (SNP) | VAF 100/346 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CYP11B2 | c.759G>A p.W253* | Nonsense Mutation (SNP) | VAF 156/479 reads (33%) | called by muse, mutect2, varscan2
- CYP2E1 | c.1373T>A p.F458Y | Missense Mutation (SNP) | VAF 136/430 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCC | c.3577C>T p.Q1193* | Nonsense Mutation (SNP) | VAF 138/414 reads (33%) | called by muse, mutect2, varscan2
- DDIAS | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- DDX42 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 103/569 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- DENND2D | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 225/360 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DGKG | c.1016G>A p.W339* | Nonsense Mutation (SNP) | VAF 80/283 reads (28%) | called by muse, mutect2, varscan2
- DHX15 | c.836T>C p.V279A | Missense Mutation (SNP) | VAF 80/265 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- DHX57 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 81/264 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLGAP1 | c.1852del p.M618Wfs*14 | Frame Shift Del (DEL) | VAF 194/681 reads (28%) | called by mutect2, pindel, varscan2
- DNAH8 | c.8527C>T p.Q2843* | Nonsense Mutation (SNP) | VAF 64/309 reads (21%) | called by muse, mutect2, varscan2
- DOCK4 | c.3328C>G p.L1110V | Missense Mutation (SNP) | VAF 99/355 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- DOCK4 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 73/254 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DRC1 | c.1592T>A p.I531N | Missense Mutation (SNP) | VAF 99/342 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- DSC3 | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 115/387 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- DSCAM | c.3154G>A p.D1052N | Missense Mutation (SNP) | VAF 119/386 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DTHD1 | c.815C>T p.S272L (on ENST00000456874; = p.S107L on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DYSF | c.2826G>A p.M942I | Missense Mutation (SNP) | VAF 114/348 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EBF1 | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 168/473 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- EEF2 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 108/454 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- EHF | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF2S3 | c.534G>C p.E178D | Missense Mutation (SNP) | VAF 131/213 reads (62%) | SIFT tolerated (0.23); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- EPB41L2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPPK1 | c.2916del p.I973Sfs*29 | Frame Shift Del (DEL) | VAF 154/574 reads (27%) | called by mutect2, pindel, varscan2
- FAM107B | c.32A>T p.N11I (on ENST00000378458 / NM_001320737.1; = p.N186I on NM_031453.3) | Missense Mutation (SNP) | VAF 137/453 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FAM160A1 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 164/563 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM189A1 | c.1469G>A p.R490K | Missense Mutation (SNP) | VAF 160/473 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM204A | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 97/280 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- FAM237A | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 129/386 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FAM83B | c.2552T>C p.V851A | Missense Mutation (SNP) | VAF 144/404 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM86B1 | c.470G>A p.S157N | Missense Mutation (SNP) | VAF 205/1197 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FBLN5 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 99/337 reads (29%) | called by muse, mutect2, varscan2
- FCAMR | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 166/780 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FCAR | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 233/790 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- FGD3 | c.1709A>G p.K570R | Missense Mutation (SNP) | VAF 129/404 reads (32%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- FLNA | c.4813_4843del p.T1605Afs*42 (on ENST00000369850 / NM_001110556.2; = p.T1605Afs*49 on NM_001456.3) | Frame Shift Del (DEL) | VAF 151/286 reads (53%) | called by mutect2, pindel, varscan2
- FMN1 | c.2149T>C p.Y717H (on ENST00000616417 / NM_001277313.2; = p.Y494H on NM_001103184.4) | Missense Mutation (SNP) | VAF 62/272 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GALNT15 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 187/506 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- GART | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 75/251 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GATA2 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 153/476 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GATAD2B | c.437T>C p.L146P | Missense Mutation (SNP) | VAF 137/785 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- GDPD1 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 101/391 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GIT1 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 84/366 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GLI1 | c.2905C>T p.P969S | Missense Mutation (SNP) | VAF 177/550 reads (32%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GLIS3 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 172/569 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLGB1 | c.6454A>T p.K2152* | Nonsense Mutation (SNP) | VAF 158/558 reads (28%) | called by muse, mutect2
- GRAMD1B | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- GRIN2A | c.2953C>T p.P985S | Missense Mutation (SNP) | VAF 116/348 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRK4 | c.334G>T p.D112Y (on ENST00000398052 / NM_182982.3; = p.D80Y on NM_005307.3) | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- GRK5 | c.891C>A p.C297* | Nonsense Mutation (SNP) | VAF 108/399 reads (27%) | called by muse, mutect2, varscan2
- GSG1 | c.497C>T p.S166F (on ENST00000651961 / NM_001080555.4; = p.I171= on NM_031289.5) | Missense Mutation (SNP) | VAF 86/267 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- GSTO2 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 155/507 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GUCY2C | c.2093C>T p.S698F | Missense Mutation (SNP) | VAF 74/293 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- HECW1 | c.1964G>A p.G655E | Missense Mutation (SNP) | VAF 163/515 reads (32%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HIVEP2 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 135/402 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSD11B1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 51/362 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- HSH2D | c.69G>A p.M23I | Missense Mutation (SNP) | VAF 176/508 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPB3 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 155/465 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHV3OR15-7 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 139/464 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- IL10RA | c.1720C>A p.L574M | Missense Mutation (SNP) | VAF 83/206 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- JARID2 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 70/361 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- JPH4 | c.1720G>A p.G574S | Missense Mutation (SNP) | VAF 182/588 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- JPH4 | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 216/652 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KALRN | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 128/430 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNJ3 | c.1448G>A p.R483K | Missense Mutation (SNP) | VAF 129/393 reads (33%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIAA0232 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 128/412 reads (31%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1217 | c.4624G>A p.E1542K | Missense Mutation (SNP) | VAF 143/448 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- KIAA2012 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 102/307 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- KIAA2026 | c.4013G>A p.G1338E | Missense Mutation (SNP) | VAF 98/399 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KIF1B | c.5426G>A p.R1809K (on ENST00000377086 / NM_001365952.1; = p.R1763K on NM_015074.3) | Missense Mutation (SNP) | VAF 195/295 reads (66%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- KIF2C | c.826A>C p.K276Q | Missense Mutation (SNP) | VAF 203/306 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KIFC2 | c.1488C>T p.G496= | Splice Region (SNP) | VAF 112/342 reads (33%) | called by muse, mutect2, varscan2
- KLF8 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 210/297 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLHL7 | c.706C>T p.P236S (on ENST00000339077 / NM_001031710.3; = p.P188S on NM_018846.5) | Missense Mutation (SNP) | VAF 119/385 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KLK6 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 89/307 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- KRTAP19-5 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 123/379 reads (32%) | SIFT tolerated, low confidence (0.96); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- L3MBTL3 | c.2077C>G p.L693V | Missense Mutation (SNP) | VAF 143/398 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- LARGE2 | c.505T>C p.W169R | Missense Mutation (SNP) | VAF 133/345 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LATS2 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 153/491 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- LCE2C | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 333/936 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LCE2D | c.228C>G p.H76Q | Missense Mutation (SNP) | VAF 418/1102 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- LIG1 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 128/408 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.056); called by muse, mutect2
- LIPK | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 136/392 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LONRF3 | c.1216C>T p.P406S (on ENST00000371628 / NM_001031855.3; = p.P365S on NM_024778.5) | Missense Mutation (SNP) | VAF 183/294 reads (62%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LPA | c.5612C>T p.S1871F | Missense Mutation (SNP) | VAF 99/325 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LPA | c.5338C>T p.P1780S | Missense Mutation (SNP) | VAF 88/281 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRK2 | c.3934G>A p.G1312R | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LTBP2 | c.2309G>A p.R770K | Missense Mutation (SNP) | VAF 185/663 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LY75 | c.4457G>A p.G1486E | Missense Mutation (SNP) | VAF 123/409 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- LYG2 | c.520+1G>A p.X174_splice | Splice Site (SNP) | VAF 150/453 reads (33%) | called by muse, mutect2, varscan2
- MAGEA6 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 190/296 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MALRD1 | c.3922G>A p.D1308N | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- MANBA | c.1261C>T p.L421F (on ENST00000642252; = p.L375F on NM_005908.4) | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARCHF10 | c.1966G>A p.G656R | Missense Mutation (SNP) | VAF 227/444 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARCHF5 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 113/370 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MARK3 | c.1160T>C p.V387A | Missense Mutation (SNP) | VAF 111/358 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MAS1L | c.997C>T p.L333F | Missense Mutation (SNP) | VAF 198/913 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- MCIDAS | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 89/306 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MEF2C | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 74/230 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- MERTK | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 88/250 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- MGAM2 | c.4466G>A p.G1489E | Missense Mutation (SNP) | VAF 86/264 reads (33%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- MMP1 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 144/323 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MOSPD3 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 152/488 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRPL11 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 139/257 reads (54%) | called by muse, mutect2, varscan2
- MTRNR2L10 | c.41G>A p.R14K | Missense Mutation (SNP) | VAF 138/204 reads (68%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- MTRR | c.56+1_56+2del p.X19_splice | Splice Site (DEL) | VAF 98/413 reads (24%) | called by mutect2, pindel, varscan2
- MUC16 | c.20473C>T p.H6825Y | Missense Mutation (SNP) | VAF 140/394 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MUC16 | c.14111C>T p.S4704L | Missense Mutation (SNP) | VAF 158/436 reads (36%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC22 | c.4291G>A p.E1431K | Missense Mutation (SNP) | VAF 133/597 reads (22%) | SIFT tolerated (0.73); called by muse, mutect2, varscan2
- MUCL3 | c.929G>A p.R310K | Missense Mutation (SNP) | VAF 275/1114 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYADML2 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 95/381 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MYC | c.802G>A p.E268K (on ENST00000377970; = p.E283K on NM_002467.6) | Missense Mutation (SNP) | VAF 109/380 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- MYLK | c.2705G>A p.G902E | Missense Mutation (SNP) | VAF 175/538 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- MYO18B | c.7432G>T p.E2478* | Nonsense Mutation (SNP) | VAF 133/415 reads (32%) | called by muse, mutect2, varscan2
- NALCN | c.5111A>G p.N1704S | Missense Mutation (SNP) | VAF 160/526 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NCAPH | c.1874C>T p.P625L | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NCOA1 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 95/342 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, varscan2
- NCOR2 | c.2455C>T p.P819S | Missense Mutation (SNP) | VAF 177/552 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NEFH | c.1301C>G p.T434S | Missense Mutation (SNP) | VAF 96/416 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- NFATC2IP | c.924del p.F308Lfs*15 | Frame Shift Del (DEL) | VAF 167/522 reads (32%) | called by mutect2, pindel, varscan2
- NMI | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 84/298 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2
- NOBOX | c.1970G>A p.G657E | Missense Mutation (SNP) | VAF 111/367 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- OAS3 | c.2501A>G p.N834S | Missense Mutation (SNP) | VAF 165/493 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OPALIN | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 88/292 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- OR14I1 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 245/659 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- OR1E1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 156/373 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- OR1M1 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 154/412 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR1N2 | c.467A>G p.N156S | Missense Mutation (SNP) | VAF 124/391 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- OR2AP1 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 130/430 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR2H2 | c.887C>T p.T296I | Missense Mutation (SNP) | VAF 172/721 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- OR2J1 | c.466A>G p.T156A | Missense Mutation (SNP) | VAF 315/603 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2J3 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 146/597 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- OR2T27 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 90/542 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- OR5K4 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 116/387 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- OR9K2 | c.545T>G p.V182G (on ENST00000305377; = p.V160G on NM_001005243.1) | Missense Mutation (SNP) | VAF 127/428 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- OTOGL | c.5888C>T p.S1963F (on ENST00000547103; = p.S1954F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/275 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- PCDHA2 | c.2070G>T p.E690D | Missense Mutation (SNP) | VAF 144/457 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PDPR | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 40/332 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2
- PIK3C2B | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 128/687 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PIK3C2B | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 78/430 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PIK3C2G | c.1388A>T p.K463I | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- PJA2 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 126/372 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCL1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 110/322 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- PLEKHA5 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 106/320 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLIN3 | c.1103A>G p.D368G | Missense Mutation (SNP) | VAF 184/539 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PLPP2 | c.572G>A p.W191* | Nonsense Mutation (SNP) | VAF 118/338 reads (35%) | called by muse, mutect2, varscan2
- PLXNB3 | c.2261C>T p.P754L | Missense Mutation (SNP) | VAF 115/195 reads (59%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PMIS2 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 136/398 reads (34%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- POGK | c.709G>C p.V237L | Missense Mutation (SNP) | VAF 105/744 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- POTEE | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 137/1146 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PPIP5K1 | c.3772T>G p.C1258G (on ENST00000396923; = p.C1233G on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 166/471 reads (35%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRKCSH | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 143/453 reads (32%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- PRLR | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 129/427 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PROSER3 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 96/325 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PRRT3 | c.321A>C p.R107S | Missense Mutation (SNP) | VAF 170/482 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PRSS16 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 138/646 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- PSG1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 112/457 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PTPN12 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PYROXD1 | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 65/222 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- QRICH2 | c.3479C>T p.S1160F | Missense Mutation (SNP) | VAF 225/475 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RADIL | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 175/606 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- RALGAPB | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 139/422 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- RAPGEF6 | c.289A>T p.K97* | Nonsense Mutation (SNP) | VAF 117/313 reads (37%) | called by muse, mutect2, varscan2
- RAPSN | c.524A>C p.Q175P | Missense Mutation (SNP) | VAF 79/158 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- RBCK1 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 176/505 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- RBM33 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 125/426 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RELN | c.6622G>A p.D2208N | Missense Mutation (SNP) | VAF 134/459 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RELN | c.4590G>T p.G1530= | Splice Region (SNP) | VAF 38/181 reads (21%) | called by muse, mutect2, varscan2
- RELN | c.2992C>T p.L998F | Missense Mutation (SNP) | VAF 91/303 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2
- RHOU | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 216/575 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- RNASE12 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 113/433 reads (26%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNASE12 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 116/438 reads (26%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROR2 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 134/445 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RSPH1 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 90/273 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- RTEL1 | c.532G>C p.V178L | Missense Mutation (SNP) | VAF 130/362 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- RYR2 | c.1906C>T p.L636F | Missense Mutation (SNP) | VAF 110/655 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SASH1 | c.2986C>T p.L996F | Missense Mutation (SNP) | VAF 153/476 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- SCN9A | c.5161C>T p.H1721Y (on ENST00000303354; = p.H1710Y on NM_002977.3) | Missense Mutation (SNP) | VAF 144/436 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- SELE | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 129/354 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SELENOV | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- SEMA3G | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 125/403 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA4A | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 185/516 reads (36%) | called by muse, mutect2, varscan2
- SEMA6D | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 134/388 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIRPB2 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 115/424 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLAMF6 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 159/806 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC35B2 | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 157/354 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC35F3 | c.1069G>A p.V357I (on ENST00000366617 / NM_001300845.1; = p.V426I on NM_173508.4) | Missense Mutation (SNP) | VAF 217/647 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- SLC44A4 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 165/416 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- SLC48A1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 153/518 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SLC5A5 | c.98G>A p.W33* | Nonsense Mutation (SNP) | VAF 114/428 reads (27%) | called by muse, mutect2, varscan2
- SLC6A11 | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 124/412 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC6A9 | c.1758T>C p.F586= (on ENST00000360584 / NM_201649.4; = p.F532= on NM_006934.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 161/265 reads (61%) | called by muse, mutect2, varscan2
- SLC7A2 | c.1549C>T p.H517Y (on ENST00000494857 / NM_001370338.1; = p.H556Y on NM_003046.6) | Missense Mutation (SNP) | VAF 122/395 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLFN14 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 237/506 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SNED1 | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 100/406 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- SNX18 | c.1255C>T p.L419F | Missense Mutation (SNP) | VAF 161/486 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPTA1 | c.4552G>T p.E1518* | Nonsense Mutation (SNP) | VAF 259/701 reads (37%) | called by muse, mutect2, varscan2
- SRGAP3 | c.2899A>C p.T967P | Missense Mutation (SNP) | VAF 118/314 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- SRP68 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 357/709 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SSC5D | c.3463C>T p.P1155S | Missense Mutation (SNP) | VAF 154/490 reads (31%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- SSTR1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 156/471 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SSU72P2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- STYXL2 | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 86/549 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SUCO | c.3682C>T p.P1228S | Missense Mutation (SNP) | VAF 254/656 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SUPT6H | c.3028C>G p.R1010G | Missense Mutation (SNP) | VAF 99/410 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TAP2 | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 170/729 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D4 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 145/433 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- TELO2 | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 129/366 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENM3 | c.3921A>T p.K1307N | Missense Mutation (SNP) | VAF 115/356 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- TEX15 | c.809G>A p.G270E (on ENST00000638951; = p.G266E on NM_001350162.2) | Missense Mutation (SNP) | VAF 89/334 reads (27%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- TGFA | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 125/420 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TGFB2 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 157/751 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TJAP1 | c.1076C>T p.S359F (on ENST00000372445 / NM_001146016.1; = p.S349F on NM_080604.3) | Missense Mutation (SNP) | VAF 179/752 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMIGD1 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 294/625 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMPRSS15 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- TNR | c.350G>A p.R117K | Missense Mutation (SNP) | VAF 266/685 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOPAZ1 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- TOPAZ1 | c.1361G>A p.G454E | Missense Mutation (SNP) | VAF 127/391 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPTE | c.619C>T p.H207Y (on ENST00000618007 / NM_199261.4; = p.H189Y on NM_199259.4) | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- TRAF3IP3 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 271/722 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRANK1 | c.5174G>A p.G1725E | Missense Mutation (SNP) | VAF 130/363 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIM10 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 240/905 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TRPM2 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 128/357 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- TRPM6 | c.1706G>A p.R569K | Missense Mutation (SNP) | VAF 103/407 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TSHR | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSPAN8 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- TSPY4 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- TTC28 | c.7046C>T p.A2349V | Missense Mutation (SNP) | VAF 158/503 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTLL2 | c.977G>A p.R326K | Missense Mutation (SNP) | VAF 178/552 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- TTLL4 | c.2174_2196del p.S725Cfs*32 | Frame Shift Del (DEL) | VAF 67/319 reads (21%) | called by mutect2, pindel, varscan2
- TTN | c.67397C>T p.P22466L (on ENST00000591111; = p.P15042L on NM_003319.4) | Missense Mutation (SNP) | VAF 135/480 reads (28%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.43621G>A p.D14541N (on ENST00000591111; = p.D7117N on NM_003319.4) | Missense Mutation (SNP) | VAF 129/436 reads (30%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.30895G>A p.V10299I (on ENST00000591111; = p.V9372I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/283 reads (31%) | PolyPhen benign (0.131); called by muse, mutect2, varscan2
- TUT7 | c.1472T>C p.L491S | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TXNDC11 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 105/326 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- UBE2Q1 | c.19C>G p.Q7E | Missense Mutation (SNP) | VAF 140/417 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBR3 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 100/318 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- UNC79 | c.903G>A p.W301* (on ENST00000393151 / NM_001346218.2; = p.W124* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 111/378 reads (29%) | called by muse, mutect2, varscan2
- UPF1 | c.2276_2278del p.F759del (on ENST00000599848 / NM_001297549.2; = p.F748del on NM_002911.4) | In Frame Del (DEL) | VAF 117/390 reads (30%) | called by pindel, varscan2
- USH2A | c.12010G>A p.E4004K | Missense Mutation (SNP) | VAF 293/694 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- USP17L18 | c.1108C>T p.L370F | Missense Mutation (SNP) | VAF 75/817 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP9Y | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 97/152 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- VASN | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 209/716 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VASN | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 205/718 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- VEGFC | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPREB3 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 150/457 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- VPS37A | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 107/331 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS52 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 384/796 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.076); called by muse, varscan2
- WASHC2A | c.3068C>T p.T1023I | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDFY4 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 153/442 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WEE2 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WNK4 | c.1638G>A p.M546I | Missense Mutation (SNP) | VAF 202/502 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); called by mutect2, varscan2
- XKR6 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XPO4 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 155/497 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- XRCC1 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 139/438 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZBTB6 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 115/344 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ZFP28 | c.1017G>A p.W339* | Nonsense Mutation (SNP) | VAF 127/371 reads (34%) | called by muse, mutect2, varscan2
- ZNF175 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 112/341 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- ZNF318 | c.6708del p.A2238Lfs*12 | Frame Shift Del (DEL) | VAF 113/537 reads (21%) | called by mutect2, pindel, varscan2
- ZNF534 | c.1088G>A p.G363E (on ENST00000332323 / NM_001143939.3; = p.G350E on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 172/557 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF543 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 144/472 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF621 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 159/528 reads (30%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- ZNF638 | c.2444C>T p.S815F | Missense Mutation (SNP) | VAF 113/345 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- ZNF831 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 183/553 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- ZNF845 | c.454C>T p.H152Y | Missense Mutation (SNP) | VAF 133/435 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ZRANB3 | c.996G>A p.M332I | Missense Mutation (SNP) | VAF 88/287 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZSWIM8 | c.1921C>T p.P641S | Missense Mutation (SNP) | VAF 182/557 reads (33%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- ABCB1 | c.612T>C p.F204= | Silent (SNP) | VAF 116/356 reads (33%) | called by muse, mutect2, varscan2
- ABR | c.2094C>T p.F698= (on ENST00000302538 / NM_021962.5; = p.F661= on NM_001092.5) | Silent (SNP) | VAF 104/198 reads (53%) | catalogued as rs758457749, COSV52141393; called by muse, varscan2
- ACOX1 | c.1467C>T p.L489= | Silent (SNP) | VAF 176/373 reads (47%) | catalogued as COSV99503218; called by muse, mutect2, varscan2
- ACTRT3 | c.909C>T p.F303= | Silent (SNP) | VAF 125/378 reads (33%) | catalogued as rs1281821207, COSV100377503; called by muse, mutect2, varscan2
- ADAMTS7 | c.2337C>T p.L779= | Silent (SNP) | VAF 114/370 reads (31%) | catalogued as rs765534592; called by muse, mutect2, varscan2
- ADAMTSL5 | c.36C>T p.L12= | Silent (SNP) | VAF 118/413 reads (29%) | catalogued as rs966326497; called by muse, mutect2, varscan2
- ADCY10 | c.1914G>A p.R638= | Silent (SNP) | VAF 197/507 reads (39%) | catalogued as COSV100896479; called by muse, mutect2, varscan2
- ADGRD2 | c.12C>T p.V4= | Silent (SNP) | VAF 89/303 reads (29%) | called by muse, mutect2, varscan2
- ADGRV1 | c.4575C>T p.F1525= | Silent (SNP) | VAF 85/283 reads (30%) | catalogued as COSV67985686; called by muse, mutect2, varscan2
- ADPRHL1 | c.1422C>T p.L474= | Silent (SNP) | VAF 111/354 reads (31%) | called by muse, mutect2, varscan2
- AFAP1L2 | c.2454T>C p.S818= (on ENST00000304129 / NM_001351075.1; = p.S814= on NM_032550.3 and 11 other RefSeq transcripts) | Silent (SNP) | VAF 88/300 reads (29%) | catalogued as COSV58412728; called by muse, mutect2, varscan2
- AGBL1 | c.2397C>T p.I799= | Silent (SNP) | VAF 79/292 reads (27%) | catalogued as rs926562357, COSV66853693; called by muse, mutect2, varscan2
- ALDH9A1 | c.1266C>T p.S422= | Silent (SNP) | VAF 132/754 reads (18%) | called by muse, mutect2, varscan2
- ANKRD55 | c.711C>T p.I237= | Silent (SNP) | VAF 154/451 reads (34%) | catalogued as rs750318320, COSV61946228; called by muse, mutect2, varscan2
- ANXA8 | c.300G>A p.K100= | Silent (SNP) | VAF 101/814 reads (12%) | called by muse, mutect2, varscan2
- APC | c.3327T>C p.G1109= | Silent (SNP) | VAF 140/432 reads (32%) | called by muse, mutect2, varscan2
- AQP10 | c.396G>A p.G132= | Silent (SNP) | VAF 123/530 reads (23%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.2157G>A p.G719= | Silent (SNP) | VAF 136/382 reads (36%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.925C>T p.L309= | Silent (SNP) | VAF 96/215 reads (45%) | catalogued as COSV52810543; called by muse, mutect2, varscan2
- ARHGAP33 | c.2604C>T p.T868= | Silent (SNP) | VAF 192/564 reads (34%) | called by muse, mutect2, varscan2
- ASB2 | c.66C>T p.S22= | Silent (SNP) | VAF 186/621 reads (30%) | called by muse, mutect2, varscan2
- ATF7IP2 | c.615C>T p.S205= | Silent (SNP) | VAF 100/358 reads (28%) | called by muse, mutect2, varscan2
- ATP8B4 | c.3357G>A p.R1119= | Silent (SNP) | VAF 127/373 reads (34%) | catalogued as COSV99466779; called by muse, mutect2, varscan2
- BBX | c.2511G>A p.R837= (on ENST00000325805 / NM_001142568.3; = p.R807= on NM_020235.7) | Silent (SNP) | VAF 122/344 reads (35%) | called by muse, mutect2, varscan2
- BCAS4 | c.15G>A p.G5= | Silent (SNP) | VAF 91/303 reads (30%) | called by muse, mutect2, varscan2
- BCL11B | c.393G>A p.T131= | Silent (SNP) | VAF 66/238 reads (28%) | catalogued as rs114557475, COSV61734229; called by muse, varscan2
- BCO2 | c.876G>A p.R292= | Silent (SNP) | VAF 53/142 reads (37%) | called by muse, mutect2, varscan2
- BIRC6 | c.12447C>T p.T4149= | Silent (SNP) | VAF 166/496 reads (33%) | called by muse, mutect2, varscan2
- BNC1 | c.750C>T p.N250= | Silent (SNP) | VAF 162/467 reads (35%) | called by muse, mutect2, varscan2
- BRAF | c.2334C>T p.F778= (on ENST00000288602 / NM_001374244.1; = p.F738= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 113/358 reads (32%) | catalogued as rs1425494134; called by muse, mutect2, varscan2
- C22orf15 | c.286C>T p.L96= | Silent (SNP) | VAF 175/549 reads (32%) | called by muse, mutect2, varscan2
- C6orf118 | c.264G>A p.G88= | Silent (SNP) | VAF 194/538 reads (36%) | catalogued as COSV57815126; called by muse, mutect2, varscan2
- C8B | c.732C>T p.V244= | Silent (SNP) | VAF 235/403 reads (58%) | called by muse, mutect2, varscan2
- CACNA1B | c.3006G>A p.T1002= | Silent (SNP) | VAF 141/504 reads (28%) | catalogued as rs1362026962; called by muse, mutect2, varscan2
- CACNA1E | c.2514G>A p.L838= | Silent (SNP) | VAF 339/904 reads (38%) | called by muse, mutect2, varscan2
- CACNB1 | c.339G>T p.P113= | Silent (SNP) | VAF 164/584 reads (28%) | catalogued as COSV59998393, COSV59999018; called by muse, mutect2, varscan2
- CALN1 | c.42G>A p.G14= (on ENST00000329008 / NM_001017440.3; = p.G56= on NM_031468.4) | Silent (SNP) | VAF 116/409 reads (28%) | catalogued as COSV61124803; called by muse, mutect2, varscan2
- CAMSAP3 | c.2586G>A p.G862= | Silent (SNP) | VAF 160/484 reads (33%) | called by muse, mutect2, varscan2
- CARD11 | c.390C>T p.F130= | Silent (SNP) | VAF 108/343 reads (31%) | called by muse, mutect2, varscan2
- CARD8 | c.456C>T p.I152= (on ENST00000651546 / NM_001184900.3; = p.I102= on NM_014959.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 105/326 reads (32%) | catalogued as rs372775777; called by muse, mutect2, varscan2
382 further variants in this file (0 protein-altering or splice-affecting, 331 silent, 51 other) are not listed here.
